Somatic mutation profile of tumor specimen ALCH-B0D8-TTP1-A (aliquot ALCH-B0D8-TTP1-A-2-0-D-A694-36) from ALCHEMIST case ALCH-B0D8, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 58.4 years (21,335 days).
Specimen ALCH-B0D8-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 63c0f78c-b7a7-447c-a208-5b24f6c4b78e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0D8-NB1-A (Blood Derived Normal), aliquot ALCH-B0D8-NB1-A-1-0-D-A695-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dc3b6f9b-2347-42d3-939b-d401469d3ade

The open-access MAF lists 51 somatic variants for this specimen: 37 protein-altering or splice-affecting, 10 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 10, Nonsense Mutation 4, Splice Region 1, 5'UTR 1, Splice Site 1, RNA 1, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHCTF1 | c.2708C>G p.P903R (on ENST00000366508; = p.P877R on NM_015446.5) | Missense Mutation (SNP) | VAF 10/141 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58251014; called by muse, mutect2
- GRIPAP1 | c.1924C>T p.R642C | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs1468936421; called by muse, mutect2
- KRTAP13-3 | c.269A>G p.N90S | Missense Mutation (SNP) | VAF 14/298 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1286632642; called by muse, mutect2
- MORC2 | c.175C>T p.R59* | Nonsense Mutation (SNP) | VAF 16/422 reads (4%) | catalogued as rs1202793669; called by muse, mutect2
- PKD1L1 | c.925G>A p.G309R | Missense Mutation (SNP) | VAF 66/569 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.297); catalogued as rs1011285694; called by muse, mutect2, varscan2
- RALGDS | c.2086C>G p.P696A | Missense Mutation (SNP) | VAF 13/229 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.119); catalogued as COSV100924323; called by muse, mutect2
- SHANK1 | c.487C>A p.Q163K | Missense Mutation (SNP) | VAF 14/385 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV99521937; called by muse, mutect2
- SYNJ2 | c.1128-2A>G p.X376_splice | Splice Site (SNP) | VAF 9/221 reads (4%) | catalogued as COSV100840044, COSV62897462; called by muse, mutect2
- TFAP2B | c.1228A>G p.I410V | Missense Mutation (SNP) | VAF 16/280 reads (6%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.935); catalogued as rs1182927469; called by muse, mutect2
- TOPAZ1 | c.3986A>G p.K1329R | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.382); catalogued as rs1384157261; called by muse, mutect2, varscan2
- AC126283.2 | c.1303A>T p.M435L | Missense Mutation (SNP) | VAF 22/490 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- AP002512.3 | c.629T>C p.V210A | Missense Mutation (SNP) | VAF 13/247 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.07); called by muse, mutect2
- BBS2 | c.1339C>T p.P447S | Missense Mutation (SNP) | VAF 23/411 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2
- BCHE | c.45G>T p.W15C | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by muse, mutect2
- C2CD5 | c.643A>T p.R215* | Nonsense Mutation (SNP) | VAF 18/440 reads (4%) | called by muse, mutect2
- CCR6 | c.883G>A p.G295S | Missense Mutation (SNP) | VAF 26/546 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.014); called by muse, mutect2
- CHST1 | c.141C>A p.C47* | Nonsense Mutation (SNP) | VAF 4/58 reads (7%) | called by muse, mutect2
- CYP3A7 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 24/690 reads (3%) | SIFT tolerated (0.47); PolyPhen benign (0.137); called by muse, mutect2
- CYTIP | c.468C>A p.N156K | Missense Mutation (SNP) | VAF 22/376 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DNAH9 | c.5125C>G p.Q1709E | Missense Mutation (SNP) | VAF 11/256 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.087); called by muse, mutect2
- FUT8 | c.16G>T p.G6C | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GAREM1 | c.1097A>T p.N366I | Missense Mutation (SNP) | VAF 10/246 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.015); called by muse, mutect2
- IFT140 | c.3325G>A p.A1109T | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- IL31RA | c.719C>A p.S240* | Nonsense Mutation (SNP) | VAF 13/331 reads (4%) | called by muse, mutect2
- ITPR3 | c.898T>C p.W300R | Missense Mutation (SNP) | VAF 10/291 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KCNT1 | c.1486G>T p.A496S (on ENST00000488444; = p.A515S on NM_020822.3) | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.5); called by muse, mutect2
- KIF2B | c.1009T>A p.F337I | Missense Mutation (SNP) | VAF 14/280 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2
- PEG3 | c.472C>A p.H158N | Missense Mutation (SNP) | VAF 15/324 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2
- PPP1R2B | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 22/516 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.035); called by muse, mutect2
- RICTOR | c.2418G>C p.L806= | Splice Region (SNP) | VAF 18/206 reads (9%) | called by muse, mutect2
- SIGLEC10 | c.250A>G p.M84V | Missense Mutation (SNP) | VAF 13/340 reads (4%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2
- TLR8 | c.2335G>C p.D779H (on ENST00000218032 / NM_138636.5; = p.D797H on NM_016610.4) | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- TMEM117 | c.1147A>T p.S383C | Missense Mutation (SNP) | VAF 12/330 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- USH2A | c.3481G>T p.G1161C | Missense Mutation (SNP) | VAF 16/452 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); called by muse, mutect2
- VN1R5 | c.604G>T p.A202S | Missense Mutation (SNP) | VAF 8/173 reads (5%) | SIFT tolerated (0.6); PolyPhen benign (0.03); called by muse, mutect2
- VWA3A | c.2234G>A p.R745K | Missense Mutation (SNP) | VAF 16/384 reads (4%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2
- ZNF676 | c.152A>G p.D51G (on ENST00000650058; = p.D19G on NM_001001411.3) | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); called by muse, mutect2
- ANKRD37 | c.453T>C p.N151= | Silent (SNP) | VAF 16/242 reads (7%) | called by muse, mutect2
- ARHGEF4 | c.1707C>T p.I569= | Silent (SNP) | VAF 18/326 reads (6%) | catalogued as rs1301651100; called by muse, mutect2
- GABRB3 | c.138G>T p.V46= | Silent (SNP) | VAF 15/367 reads (4%) | called by muse, mutect2
- LAMA4 | c.417G>A p.L139= | Silent (SNP) | VAF 20/468 reads (4%) | called by muse, mutect2
- MFSD9 | c.870G>T p.L290= | Silent (SNP) | VAF 18/464 reads (4%) | called by muse, mutect2
- OR52E4 | c.417C>A p.T139= | Silent (SNP) | VAF 11/252 reads (4%) | called by muse, mutect2
- PIK3C2G | c.2616G>A p.E872= (on ENST00000676171; = p.E831= on NM_004570.5) | Silent (SNP) | VAF 10/99 reads (10%) | called by muse, mutect2
- PKP2 | c.333A>G p.L111= | Silent (SNP) | VAF 20/278 reads (7%) | catalogued as rs1309112416; called by muse, mutect2
- TRHR | c.594C>A p.V198= | Silent (SNP) | VAF 14/202 reads (7%) | catalogued as COSV100304892; called by muse, mutect2
- ZNF835 | c.354C>T p.A118= | Silent (SNP) | VAF 9/242 reads (4%) | called by muse, mutect2
- CACTIN | c.*371G>A | 3'UTR (SNP) | VAF 16/290 reads (6%) | catalogued as rs1018376350, COSV50269645; called by muse, mutect2
- ERVV-1 | chr19:53010208 G>T | 5'Flank (SNP) | VAF 8/143 reads (6%) | called by muse, mutect2
- OR4C4P | n.432G>T | RNA (SNP) | VAF 22/580 reads (4%) | called by muse, mutect2
- RFX6 | c.-1G>A | 5'UTR (SNP) | VAF 9/157 reads (6%) | called by muse, mutect2
